Somatic mutation profile of tumor specimen MMRF_1570_1_BM_CD138pos (aliquot MMRF_1570_1_BM_CD138pos_T1_KBS5U_L03476) from MMRF case MMRF_1570, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,372 days).
Specimen MMRF_1570_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e9251e8-c43e-424e-8496-4c27a7f39638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1570_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1570_1_PB_Whole_C2_KBS5U_L03488; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b865d22-47f7-4e0d-ab72-b920df93c1ed

The open-access MAF lists 56 somatic variants for this specimen: 25 protein-altering or splice-affecting, 11 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 11, 3'UTR 10, Intron 5, 5'UTR 2, 5'Flank 2, Nonsense Mutation 2, Nonstop Mutation 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNHD1 | c.9838G>A p.E3280K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54431157; called by muse, mutect2, varscan2
- FAM83A | c.989C>T p.T330M | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs763235881; called by muse, mutect2, varscan2
- FOXN4 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as rs1037108889; called by muse, mutect2, varscan2
- IGHV3-30 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.145); catalogued as rs778453550; called by muse, varscan2
- NLGN4X | c.2362G>A p.G788R | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV52039786, COSV99323267; called by muse, mutect2
- PTCHD3 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.56); catalogued as rs147881350; called by muse, mutect2, varscan2
- PTPRD | c.5356G>T p.E1786* | Nonsense Mutation (SNP) | VAF 29/94 reads (31%) | catalogued as COSV61937192, COSV61946549; called by muse, mutect2, varscan2
- RYR2 | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63719733; called by muse, mutect2
- UBE4A | c.721+1G>A p.X241_splice (on ENST00000252108 / NM_001204077.2; = p.R241H on NM_004788.4) | Splice Site (SNP) | VAF 14/148 reads (9%) | catalogued as rs754706178; called by muse, mutect2
- ZNF287 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs759758331; called by muse, mutect2, varscan2
- BBS7 | c.1893A>T p.E631D | Missense Mutation (SNP) | VAF 112/189 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- FAM166B | c.56T>C p.I19T | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FKRP | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FSCN1 | c.433_434dup p.S146Tfs*11 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- GPR6 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GRIN2C | c.3341G>A p.C1114Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HOXB3 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAB13 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RTL9 | c.3778G>T p.A1260S | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2
- TANC1 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- TMEM240 | c.521G>T p.*174Lext*65 | Nonstop Mutation (SNP) | VAF 69/126 reads (55%) | called by muse, mutect2, varscan2
- TMEM255A | c.983G>T p.S328I | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- TRAM1L1 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- ZNF462 | c.2582A>C p.H861P | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF674 | c.1673G>A p.C558Y | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EHHADH | c.1332G>A p.E444= | Silent (SNP) | VAF 5/149 reads (3%) | called by muse, mutect2
- HSD17B11 | c.660C>T p.F220= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs1308272269; called by muse, mutect2
- HTR2C | c.1251G>A p.R417= | Silent (SNP) | VAF 33/412 reads (8%) | catalogued as rs1556487312, COSV52223032; called by muse, mutect2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 37/38 reads (97%) | catalogued as rs367953381; called by muse, varscan2
- IGLV4-60 | c.249T>C p.V83= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs778294598; called by muse, varscan2
- IGLV4-60 | c.315T>C p.F105= | Silent (SNP) | VAF 20/69 reads (29%) | called by muse, varscan2
- KLHL38 | c.507G>A p.S169= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs754135867; called by muse, mutect2, varscan2
- OR5A2 | c.6T>A p.A2= | Silent (SNP) | VAF 53/297 reads (18%) | called by muse, mutect2, varscan2
- PACSIN3 | c.831C>T p.D277= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as rs563675998, COSV54065973, COSV54067516; called by muse, mutect2, varscan2
- RTL9 | c.3777G>C p.L1259= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- SIX3 | c.951C>A p.G317= | Silent (SNP) | VAF 15/207 reads (7%) | called by muse, mutect2
- AC093536.1 | n.33C>T | RNA (SNP) | VAF 9/115 reads (8%) | called by muse, mutect2
- ARHGEF38 | c.*840T>C | 3'UTR (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- ASB5 | c.-62G>A | 5'UTR (SNP) | VAF 60/197 reads (30%) | catalogued as rs1002128362; called by muse, mutect2, varscan2
- C1QTNF12 | c.731+57C>T | Intron (SNP) | VAF 49/88 reads (56%) | called by muse, mutect2, varscan2
- CCDC146 | chr7:77119584 T>C | 5'Flank (SNP) | VAF 11/203 reads (5%) | called by muse, mutect2
- CDK18 | c.*268dup | 3'UTR (INS) | VAF 46/110 reads (42%) | catalogued as rs935600520; called by mutect2, varscan2
- DNAH14 | c.1825+855T>C | Intron (SNP) | VAF 24/53 reads (45%) | catalogued as rs753646518; called by muse, mutect2, varscan2
- IGLL5 | c.-210C>G | 5'UTR (SNP) | VAF 20/44 reads (45%) | catalogued as COSV73251141; called by muse, mutect2, varscan2
- MAN2C1 | c.228-189T>G | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- OR5H14 | c.*50C>T | 3'UTR (SNP) | VAF 11/163 reads (7%) | called by muse, mutect2
- PCDHAC1 | c.*162G>A | 3'UTR (SNP) | VAF 23/466 reads (5%) | called by muse, mutect2
- PPP1R3A | c.*112G>T | 3'UTR (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
- PRLR | c.*842A>T | 3'UTR (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- RPS8 | c.4+16C>T | Intron (SNP) | VAF 48/107 reads (45%) | catalogued as rs1465743163; called by muse, mutect2, varscan2
- SLC11A2 | c.122-525A>T | Intron (SNP) | VAF 119/256 reads (46%) | catalogued as rs147818843; called by muse, mutect2, varscan2
- SRPK3 | chrX:153778357 A>G | 5'Flank (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- TENM4 | c.*1182G>C | 3'UTR (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- TXNDC5 | c.*1157C>G | 3'UTR (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- UGGT1 | c.*4085T>C | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ZFHX4 | c.*1973A>C | 3'UTR (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
